Somatic mutation profile of cancer-model specimen HCM-CSHL-0153-C50-85E (3D Organoid, passage 8; aliquot HCM-CSHL-0153-C50-85E-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0153-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.7 years (22,886 days).
Specimen HCM-CSHL-0153-C50-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a345eb-60f1-4831-8449-3c32b2fdfcda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0153-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0153-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/682668ee-aa2b-4475-991b-2ef0aada38ae

The open-access MAF lists 42 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 32, Silent 8, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 210/447 reads (47%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CRLF1 | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 33/329 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs866883988; called by muse, mutect2, varscan2
- CROCC | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 81/1052 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752671450; called by muse, mutect2
- DISP2 | c.3152G>A p.R1051H | Missense Mutation (SNP) | VAF 209/434 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1268388389, COSV99140760; called by muse, varscan2
- DOCK1 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757225154; called by muse, mutect2, varscan2
- HIPK2 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 507/779 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs745902293; called by muse, mutect2, varscan2
- HMCN1 | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 76/689 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54924306; called by muse, mutect2, varscan2
- HMCN1 | c.4405C>T p.R1469C | Missense Mutation (SNP) | VAF 143/685 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as rs140363573; called by muse, mutect2, varscan2
- ICE1 | c.595A>T p.I199L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs993126874, COSV56819206, COSV56833104; called by muse, mutect2, varscan2
- INPP5D | c.1316C>T p.A439V (on ENST00000445964 / NM_001017915.3; = p.A438V on NM_005541.5) | Missense Mutation (SNP) | VAF 232/467 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV64039215; called by muse, varscan2
- KCNMB3 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs893197704, COSV62895843; called by muse, mutect2, varscan2
- KIF1B | c.5083G>A p.E1695K (on ENST00000377086 / NM_001365952.1; = p.E1649K on NM_015074.3) | Missense Mutation (SNP) | VAF 111/205 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55808224; called by muse, mutect2, varscan2
- MRTFA | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931221; called by muse, mutect2, varscan2
- NIPAL4 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 156/315 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs772226292, COSV61730646; called by muse, mutect2, varscan2
- PAPOLB | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV68202658; called by muse, mutect2
- SPTA1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 68/507 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs765819340, COSV100935290; called by muse, mutect2, varscan2
- TTC6 | c.106T>C p.F36L (on ENST00000267368; = p.F1305L on NM_001310135.3) | Missense Mutation (SNP) | VAF 147/276 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747190657; called by muse, mutect2, varscan2
- USP28 | c.2812C>T p.R938W | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs61760223; called by muse, mutect2, varscan2
- WDR86 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 481/731 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200864938; called by muse, mutect2, varscan2
- ARHGEF9 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARSK | c.1588C>G p.H530D | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH1 | c.801dup p.K268* | Frame Shift Ins (INS) | VAF 181/257 reads (70%) | called by mutect2, pindel, varscan2
- DOCK3 | c.5971G>A p.V1991M | Missense Mutation (SNP) | VAF 287/591 reads (49%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPA1P48 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 211/213 reads (99%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0232 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICU2 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by mutect2, varscan2
- PCSK5 | c.4723G>T p.G1575W | Missense Mutation (SNP) | VAF 217/432 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- RYR2 | c.8659G>A p.E2887K | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- SF3B6 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SMG1 | c.7439A>T p.E2480V | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM8 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 243/529 reads (46%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF33B | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF658 | c.601_630del p.K201_T210del | In Frame Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- ZNF723 | c.367T>A p.C123S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCR9 | c.783C>T p.T261= (on ENST00000357632 / NM_031200.3; = p.T249= on NM_006641.4) | Silent (SNP) | VAF 151/304 reads (50%) | catalogued as rs759541158, COSV62940134; called by muse, mutect2, varscan2
- HCLS1 | c.783G>T p.V261= | Silent (SNP) | VAF 51/533 reads (10%) | called by muse, mutect2
- LIG3 | c.126T>C p.D42= | Silent (SNP) | VAF 13/433 reads (3%) | called by muse, mutect2
- LTBP4 | c.3366G>A p.P1122= (on ENST00000308370 / NM_001042544.1; = p.P1085= on NM_003573.2) | Silent (SNP) | VAF 211/413 reads (51%) | catalogued as rs371166802, COSV52578764; called by muse, mutect2, varscan2
- PCDH18 | c.1923C>T p.N641= | Silent (SNP) | VAF 180/365 reads (49%) | catalogued as rs377716033; called by muse, mutect2, varscan2
- VTA1 | c.864A>G p.V288= | Silent (SNP) | VAF 16/436 reads (4%) | called by muse, mutect2
- WDFY4 | c.6483G>A p.P2161= | Silent (SNP) | VAF 166/338 reads (49%) | catalogued as rs562274935, COSV55443922; called by muse, mutect2
- ZSWIM9 | c.1272G>A p.A424= | Silent (SNP) | VAF 26/790 reads (3%) | catalogued as rs1180998297; called by muse, mutect2
